Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CT, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CT-01A (Primary Tumor).

Surgical Pathology Report

Department of Pathology,
Tel: Fax:

DOB
Physician:

Sex: F

Collected.

Received: (

Case type: Surgical Case

Accession.

DIAGNOSIS

- (A) LEFT MODIFIED NECK DISSECTION, TOTAL THYROIDECTOMY, PARTIAL ESOPHAGECTOMY, BILATERAL DISSECTION AND SUPERIOR MEDIASTINAL DISSECTION:
PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT WITH EXTENSION INTO MATED LYMPH NODES AND SOFT TISSUE.
METASTATIC PAPILLARY THYROID CARCINOMA IN TWO OF THE 17 IDENTIFIABLE LYMPH NODES.
- (B) LYMPH NODE, RIGHT PARATHYROID:
Parathyroid gland with microadenoma.
No lymph node tissue present.
- (C) DISTAL ESOPHAGEAL MARGIN;
Mild esophagitis.

ICD-0-3
C83.0 carcinoma, papillary, thyroid 8360/3
Path: Carcinoma, papillary, follicular variant
8340/3
Site: thyroid, nos C73.9

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) LEFT MODIFIED NECK DISSECTION TOTAL THYROIDECTOMY, PARTIAL ESOPHAGECTOMY AND BILATERAL NECK DISSECTION AND SUPERIOR MEDIASTINAL DISSECTION - Multinodular cohesive mass with overall measurement of 12.0 x 8.0 x 8.0 cm. Multiple enlarged and firm nodules are noted some of them are matted and others are individual ranging in size from 4.0 to 1.0 cm in size. Only the left thyroid could be identified and measure 6.0 x 3.0 x 1.0 cm. The left thyroid lobe is fleshy with multiple nodules ranging in size from 1.0 to 0.5 cm. Representative sections are submitted from thyroid and different masses in A1-A36. The rest of the specimen will be bagged.
- (B) LYMPH NODE RIGHT PARATYROID - A single lymph node measuring 1.5 x 0.6 x 0.3 cm. Submitted in toto in B.
- (C) DISTAL ESOPHAGEAL MARGIN - A tan-pink non-oriented irregular fragment of tissue measuring 2.0 x 1.0 x 0.2 cm. The specimen is bisected and entirely submitted in C.

CLINICAL HISTORY

None given.

SNOMED CODES

T-B6000, M-83406, T-B7000, M-Y3370

*Some tests reported here may have been developed and performance characteristics determined by

Released by: IV...

These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Source: NCI Genomic Data Commons file ee21bc9b-4cd7-4aa4-912d-cc6e3f22224b (TCGA-EL-A3CT.981D4559-E404-470A-A25D-8B11296843ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).